Somatic mutation profile of tumor specimen ER-AC0F-TTP2-A (aliquot ER-AC0F-TTP2-A-1-0-D-A599-35) from EXCEPTIONAL_RESPONDERS case ER-AC0F, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.2 years (21,260 days).
Specimen ER-AC0F-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83046fad-871e-4ca7-a2a6-0b6358e7873c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AC0F-NT1-A (Solid Tissue Normal), aliquot ER-AC0F-NT1-A-2-0-D-A599-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71dc481a-6528-4988-8524-e0dc90061911

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 103/259 reads (40%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EPHB1 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 136/389 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs534330476, COSV67653771, COSV67669910; called by muse, mutect2, varscan2
